Somatic mutation profile of tumor specimen 0DBD15 from CCDI case PBBKTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,627 days).
Specimen 0DBD15: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67623b97-9ee8-4208-97c1-7f7da7dddfc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBD1C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0d1c1ef-dd80-425c-83ab-42574cc6db95

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 2, Silent 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- THRB | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 251/615 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs121918698, CM153085, CM910370; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GIMAP8 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 257/870 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs576578780, COSV56231919; called by muse, mutect2, varscan2
- MYF5 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 22/779 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as COSV57356706; called by muse, mutect2
- MYH3 | c.3526C>T p.R1176C | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1422222290; called by muse, mutect2
- PIP4K2C | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 189/440 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs368437479; called by muse, mutect2, varscan2
- RBFOX1 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 81/612 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs145006582, COSV60945907; called by muse, mutect2, varscan2
- SEMA3D | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 42/1026 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as rs143869872; called by muse, mutect2
- SIRT4 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 68/526 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770666458, COSV99177443; called by muse, mutect2, varscan2
- SMCHD1 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 108/1162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1211151, COSV55255086; called by muse, mutect2
- SPINK5 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 146/793 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs182767534, COSV56264044, COSV99806833; called by muse, mutect2, varscan2
- PRR16 | c.799A>G p.M267V (on ENST00000407149 / NM_001300783.2; = p.M244V on NM_016644.2) | Missense Mutation (SNP) | VAF 216/500 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIP13 | c.1075A>T p.I359F | Missense Mutation (SNP) | VAF 326/767 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC37A2 | c.471T>C p.R157= | Silent (SNP) | VAF 40/331 reads (12%) | called by muse, mutect2, varscan2
- RET | c.156C>T p.Y52= | Silent (SNP) | VAF 127/266 reads (48%) | catalogued as rs866099980, COSV60694596; ClinVar: likely benign; called by muse, mutect2, varscan2
- CBLB | c.2570-62T>A | Intron (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- NCF1 | c.575-16C>T | Intron (SNP) | VAF 43/171 reads (25%) | catalogued as rs782680047; called by muse, mutect2, varscan2
- TIGD1 | c.*3469G>A | 3'UTR (SNP) | VAF 70/211 reads (33%) | called by muse, mutect2, varscan2
- VANGL2 | c.-86C>T | 5'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as rs984033913; called by muse, mutect2
